Gene-level copy-number profile of tumor specimen TCGA-ZM-AA0E-01A from TCGA case TCGA-ZM-AA0E, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 39.0 years (14,255 days).
Specimen TCGA-ZM-AA0E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.0f2146a6-c393-48b3-b3cf-e445cbb30345.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZM-AA0E-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/64767e11-1eaf-4d46-9398-386ae215c4d5

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 980; copy number 2: 11,487; copy number 3: 33,595; copy number 4: 8,436; copy number 5: 1,457; copy number 6: 2,858; copy number 8: 992.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZM-AA0E-01A-12D-A434-01): tumor purity 0.28, ploidy 3.12, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 992 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:66,767–47,593,440, 992 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 980. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
